TCGA case TCGA-EK-A2RA — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri; Tissue source site: Gynecologic Oncology Group. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ada77320-fd05-4e43-be72-864391044b35

Demographics
Sex at birth: female; Ethnicity: hispanic or latino; Country of residence at enrollment: United States; Age at index: 74 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, large cell, nonkeratinizing, NOS: ICD-O-3 morphology code: 8072/3; ICD-10 code: C53.9; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 74.5 years (27,209 days); Year of diagnosis: 2011; Method of diagnosis: Surgical Resection; AJCC pathologic T: T2a2; AJCC pathologic N: N0; AJCC pathologic M: MX; FIGO stage: Stage IIA2; FIGO staging edition year: 2009; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Uterus.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 32; Lymphatic invasion present: No.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (5 entries)
- Day 0 (preoperative): ECOG performance status: 0.
- Day 5 (preoperative): ECOG performance status: 0.
- Days to follow up: 302 days; Disease response: With Tumor.
- Days to follow up: 489 days (1.3 years); Disease response: With Tumor.
- Follow-up contact recording only the day: day 1,246.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Hysterectomy type: Hysterectomy, NOS.
- Timepoint category: Initial Diagnosis; Weight: 72 kg; Height: 160 cm; BMI: 28.1.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Tobacco smoking quit year: 2010; Age at onset: 41.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-EK-A2RA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 130 mg.
  Slide TCGA-EK-A2RA-01A-01-TS1: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 65; Percent normal cells: 15; Percent necrosis: 3; Percent stromal cells: 22; Percent lymphocyte infiltration: 25; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-EK-A2RA-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Tobacco smoking history indicator: 4; Submitted tumor site: Cervical; Histologic diagnosis: Cervical Squamous Cell Carcinoma; Keratinization squamous cell: Non-keratinizing squamous cell carcinoma; Method initial path diagnosis: Other method, specify:; Method initial path diagnosis other: aortic and pelvic lymphadenectomy, total abdominal hysterectomy and BSO; Hysterectomy type: Total Abdominal Hysterectomy; Lymph nodes examined: Yes; Lymphovascular invasion: Absent; Corpus involvement: Present; Days to ct scan ab pelvis: 30.
- Follow-up form 1: Lost to follow-up: Yes; Tumor status: With tumor; Days from index date to performance status: 5; Treatment outcome at TCGA followup: Stable Disease; New tumor event diagnosis indicator: No.
- Follow-up form 2: Lost to follow-up: No; Treatment outcome at TCGA followup: Complete Response; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,246 days; disease-specific survival: no event (censored), 1,246 days; progression-free interval: no event (censored), 1,246 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-EK-A2RA-01A-11D-A18H-01): tumor purity 0.64, ploidy 3.5, whole-genome doublings 2.
